Somatic mutation profile of tumor specimen MMRF_2168_1_BM_CD138pos (aliquot MMRF_2168_1_BM_CD138pos_T1_KHS5U_L09526) from MMRF case MMRF_2168, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.9 years (18,590 days).
Specimen MMRF_2168_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 161d3fce-e245-49c7-91b5-2e4a374d2e14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2168_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2168_1_PB_Whole_C3_KHS5U_L09527; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdf8e3c5-6cbc-45be-9973-d69ea665f01f

The open-access MAF lists 48 somatic variants for this specimen: 27 protein-altering or splice-affecting, 5 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, 3'UTR 9, Intron 6, Silent 5, Splice Site 2, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1H | c.1939G>A p.G647S | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147702970; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPO | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55939556; called by muse, mutect2, varscan2
- EIF4B | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.928); catalogued as rs765495559; called by muse, mutect2, varscan2
- FAT1 | c.12925C>T p.P4309S | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs933073497, COSV71673415; called by muse, mutect2, varscan2
- GALNT3 | c.904G>T p.V302L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs765239589, COSV101205035; called by muse, mutect2, varscan2
- GPNMB | c.1240G>A p.V414M (on ENST00000381990 / NM_001005340.2; = p.V402M on NM_002510.3) | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs146238405; called by muse, mutect2, varscan2
- IGHV2-70D | c.281C>T p.T94I | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1290963643; called by muse, varscan2
- IGHV2-70D | c.235T>C p.F79L | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1457244699; called by muse, varscan2
- SF3B3 | c.3646G>A p.A1216T | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs769036151, COSV100210172; called by mutect2, varscan2
- SZT2 | c.5375G>A p.G1792E (on ENST00000634258 / NM_001365999.1; = p.G1735E on NM_015284.4) | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs959466789; called by muse, mutect2, varscan2
- VEPH1 | c.1271G>A p.G424D | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV100747494; called by muse, mutect2, varscan2
- AIMP1 | c.110-1G>C p.X37_splice | Splice Site (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2
- APBB1IP | c.113C>A p.P38Q | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- ARHGEF10L | c.3072C>A p.S1024R | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATP8A2 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAZ2A | c.2380_2407del p.A794Hfs*13 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | called by mutect2, pindel, varscan2
- ELOA2 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by mutect2, varscan2
- GSTCD | c.860A>T p.D287V (on ENST00000360505 / NM_001031720.3; = p.D200V on NM_024751.3) | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HUWE1 | c.7522T>C p.S2508P | Missense Mutation (SNP) | VAF 31/32 reads (97%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- IGHV2-70D | c.266C>G p.T89S | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, varscan2
- IGHV2-70D | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- IGHV3-64 | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 44/56 reads (79%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.669); called by muse, varscan2
- MEN1 | c.77A>G p.E26G | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); called by muse, mutect2
- MROH2B | c.1543-2A>G p.X515_splice | Splice Site (SNP) | VAF 94/102 reads (92%) | called by muse, varscan2
- PHKB | c.2804A>G p.N935S | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- TTLL11 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZNF799 | c.396G>T p.E132D | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP2B2 | c.1719C>T p.Y573= (on ENST00000352432; = p.Y539= on NM_001683.5) | Silent (SNP) | VAF 52/142 reads (37%) | catalogued as rs143161877; called by muse, mutect2, varscan2
- IGHV2-70D | c.282C>T p.T94= | Silent (SNP) | VAF 30/54 reads (56%) | called by muse, varscan2
- IGHV2-70D | c.138C>T p.F46= | Silent (SNP) | VAF 36/64 reads (56%) | called by muse, varscan2
- SOCS1 | c.495G>A p.P165= | Silent (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- SPRYD4 | c.114C>A p.T38= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs773611493; called by mutect2, varscan2
- ADAMTS2 | c.*1447C>T | 3'UTR (SNP) | VAF 25/78 reads (32%) | catalogued as rs900873183; called by muse, mutect2, varscan2
- C21orf58 | c.445-81C>T | Intron (SNP) | VAF 37/187 reads (20%) | called by muse, mutect2, varscan2
- CD34 | c.598-218A>G | Intron (SNP) | VAF 22/33 reads (67%) | called by muse, mutect2, varscan2
- CNTLN | c.1146+240T>C | Intron (SNP) | VAF 36/95 reads (38%) | called by mutect2, varscan2
- GFRA1 | c.*85C>T | 3'UTR (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- GRAP2 | c.*1223G>C | 3'UTR (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- HNF4G | chr8:75564564 C>T | 3'Flank (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- LARS2 | c.*165A>C | 3'UTR (SNP) | VAF 76/140 reads (54%) | called by muse, mutect2, varscan2
- LRAT | c.*1795T>A | 3'UTR (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- NMT1 | c.1471-14G>C | Intron (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- NOX4 | c.*1703A>T | 3'UTR (SNP) | VAF 98/149 reads (66%) | called by muse, mutect2, varscan2
- OXGR1 | c.*478T>C | 3'UTR (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- PIM1 | c.*918_*921dup | 3'UTR (INS) | VAF 24/60 reads (40%) | catalogued as rs750512911; called by mutect2, varscan2
- SOX11 | c.*3306C>T | 3'UTR (SNP) | VAF 80/179 reads (45%) | called by muse, mutect2, varscan2
- TANC1 | c.495+12G>A | Intron (SNP) | VAF 58/143 reads (41%) | called by mutect2, varscan2
- USH2A | c.4627+725A>C | Intron (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
